Somatic mutation profile of tumor specimen MBCProject_0345_T1_WES (aliquot MBCProject_0345_T1_WES_1) from CMI case MBCProject_0345, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 57.4 years (20,961 days).
Specimen MBCProject_0345_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3016b92e-4bd0-49b7-813c-d52a353f621c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0345_SALIVA (Saliva), aliquot MBCProject_0345_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e6ffc17-0aca-403b-91d7-4d8560edf5fa

The open-access MAF lists 315 somatic variants for this specimen: 191 protein-altering or splice-affecting, 76 silent, 48 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 169, Silent 76, Intron 25, Nonsense Mutation 15, 3'UTR 7, 5'UTR 5, RNA 5, 5'Flank 5, Frame Shift Del 3, Splice Site 2, Splice Region 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RPGR | c.752G>A p.G251D | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555966699; ClinVar: likely pathogenic; called by mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 14/128 reads (11%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by mutect2, varscan2
- ABCF3 | c.848C>G p.S283C | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as rs773096504; called by muse, mutect2, varscan2
- ACTB | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 45/663 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.026); catalogued as COSV100079440; called by muse, mutect2
- ANKRD11 | c.1742C>T p.S581F | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1376769382, COSV56369831, COSV99969038; called by muse, mutect2, varscan2
- ARID1A | c.5372C>G p.S1791* | Nonsense Mutation (SNP) | VAF 7/54 reads (13%) | catalogued as COSV61386561, COSV61392880; called by muse, mutect2, varscan2
- ATP13A4 | c.3529G>T p.E1177* | Nonsense Mutation (SNP) | VAF 10/46 reads (22%) | catalogued as COSV61323456; called by muse, mutect2, varscan2
- BCL11B | c.2294C>T p.S765L (on ENST00000357195 / NM_001282237.2; = p.S694L on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/212 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1220663516, COSV61733464; called by muse, mutect2, varscan2
- BNC2 | c.73G>C p.D25H | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV66153464; called by muse, mutect2, varscan2
- CD248 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.365); catalogued as rs991947564; called by muse, varscan2
- DPH3 | c.19G>T p.E7* | Nonsense Mutation (SNP) | VAF 14/156 reads (9%) | catalogued as COSV53265080; called by muse, mutect2
- DUOX1 | c.376C>G p.R126G | Missense Mutation (SNP) | VAF 28/198 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.175); catalogued as rs1401034365; called by muse, mutect2, varscan2
- EFS | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as COSV53731517; called by muse, mutect2, varscan2
- ESRP2 | c.262G>C p.E88Q | Missense Mutation (SNP) | VAF 26/201 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.071); catalogued as rs779673530, COSV52175499, COSV52176591; called by muse, mutect2, varscan2
- FANCM | c.3587G>T p.R1196L | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.79); PolyPhen benign (0.007); catalogued as COSV57497789; called by mutect2, varscan2
- FTO | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.315); catalogued as rs762749778; called by muse, mutect2, varscan2
- GABRA5 | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59481768, COSV59482123; called by muse, mutect2, varscan2
- GABRG2 | c.187G>C p.E63Q | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as COSV62715623; called by muse, varscan2
- GRIK2 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as rs748577917, COSV59715646, COSV59716489, COSV59748818; called by mutect2, varscan2
- GRM3 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 27/203 reads (13%) | SIFT tolerated (0.83); PolyPhen probably damaging (0.91); catalogued as rs867081921, COSV64468953; called by muse, mutect2, varscan2
- HFM1 | c.1474C>G p.Q492E | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV99647072; called by muse, mutect2
- HORMAD1 | c.1127C>G p.S376C | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV55046229, COSV55047800; called by muse, mutect2
- HPS5 | c.578C>T p.S193L (on ENST00000349215 / NM_181507.2; = p.S79L on NM_007216.4) | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs906141169; called by muse, mutect2, varscan2
- IGHA2 | c.181G>A p.G61R | Missense Mutation (SNP) | VAF 21/209 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.275); catalogued as rs369298543; called by muse, mutect2
- IGHV3-43 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.009); catalogued as rs1424267873; called by muse, mutect2, varscan2
- IRX5 | c.1415C>G p.S472C | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as rs535761760; called by muse, mutect2, varscan2
- KAT14 | c.790C>T p.R264* | Nonsense Mutation (SNP) | VAF 15/125 reads (12%) | catalogued as rs773402956; called by mutect2, varscan2
- LRP8 | c.202G>C p.E68Q | Missense Mutation (SNP) | VAF 13/166 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.959); catalogued as rs1352452647; called by muse, mutect2
- MFN2 | c.257G>C p.R86T | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV52420413; called by muse, mutect2, varscan2
- MSL1 | c.1790G>A p.R597Q (on ENST00000398532 / NM_001365919.1; = p.R334Q on NM_001012241.2) | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.852); catalogued as rs866867277; called by muse, mutect2, varscan2
- MTARC1 | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100856234; called by muse, mutect2, varscan2
- MYH3 | c.2813C>T p.T938M | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as rs148835368; called by mutect2, varscan2
- MYH3 | c.75C>G p.I25M | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.019); catalogued as COSV56868081; called by muse, mutect2, varscan2
- MYO15A | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs200234990, COSV52756780; called by muse, mutect2, varscan2
- NOTCH3 | c.6076C>T p.Q2026* | Nonsense Mutation (SNP) | VAF 16/186 reads (9%) | catalogued as COSV54633789; called by muse, mutect2
- OGDHL | c.633C>A p.F211L | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.362); catalogued as COSV65103622; called by muse, mutect2, varscan2
- OR4C3 | c.674C>T p.S225F | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs747506989; called by mutect2, varscan2
- OR6T1 | c.818G>T p.G273V | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT tolerated (0.83); PolyPhen benign (0.017); catalogued as COSV100189788; called by muse, mutect2, varscan2
- PANK2 | c.290C>G p.S97C | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs534040675, COSV57256461; called by mutect2, varscan2
- PARP14 | c.4956G>C p.Q1652H | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101506219; called by muse, mutect2, varscan2
- PCLO | c.11368G>A p.E3790K | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV61617404, COSV61652023; called by muse, mutect2, varscan2
- PDE10A | c.1551G>C p.K517N | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100605696; called by muse, mutect2, varscan2
- PIK3CG | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100783114, COSV63245916; called by muse, mutect2, varscan2
- PKHD1 | c.8411T>C p.M2804T | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as CM100414, COSV61891176; called by muse, mutect2
- PKIG | c.91G>C p.E31Q | Missense Mutation (SNP) | VAF 19/185 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.019); catalogued as rs1241829812; called by muse, mutect2, varscan2
- PPP3CA | c.365G>C p.R122T | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59929370; called by muse, mutect2, varscan2
- PUS7 | c.916C>T p.L306F | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.164); catalogued as rs942656634; called by muse, varscan2
- PYGO2 | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1408726452; called by muse, mutect2
- RGL3 | c.1864G>A p.D622N | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs747582026; called by mutect2, varscan2
- RGS11 | c.358G>C p.E120Q (on ENST00000397770 / NM_183337.3; = p.E99Q on NM_003834.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.827); catalogued as COSV51452435; called by muse, mutect2, varscan2
- RTEL1 | c.707G>C p.R236T | Missense Mutation (SNP) | VAF 17/167 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as COSV100541589; called by muse, mutect2, varscan2
- RXYLT1 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV104370798, COSV54170365; called by muse, mutect2, varscan2
- SH3D19 | c.1841G>A p.R614Q | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as rs1209851220; called by muse, mutect2, varscan2
- SIRT1 | c.1628G>A p.R543K | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.054); catalogued as COSV53017978; called by muse, mutect2, varscan2
- SLC27A1 | c.1333G>A p.G445R | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375018539; called by mutect2, varscan2
- SLC36A1 | c.815T>G p.I272S | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV54653623; called by muse, mutect2, varscan2
- SLX4 | c.3933C>G p.I1311M | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.095); catalogued as rs374311917; called by muse, mutect2, varscan2
- SORL1 | c.733C>T p.Q245* | Nonsense Mutation (SNP) | VAF 7/58 reads (12%) | catalogued as COSV104390835; called by muse, mutect2, varscan2
- SYMPK | c.2889C>G p.I963M | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.202); catalogued as rs781194558; called by muse, mutect2, varscan2
- SYT10 | c.16G>T p.E6* | Nonsense Mutation (SNP) | VAF 14/43 reads (33%) | catalogued as COSV57341113; called by muse, mutect2
- TCEAL1 | c.403G>C p.E135Q | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1324833971; called by muse, mutect2, varscan2
- TEK | c.1444C>G p.L482V | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.12); catalogued as rs1275357194; called by muse, mutect2, varscan2
- TMPO | c.1952G>A p.R651Q | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1032297714; called by muse, mutect2, varscan2
- TMPRSS6 | c.1537G>T p.E513* | Nonsense Mutation (SNP) | VAF 6/34 reads (18%) | catalogued as CM093222, COSV60977986, COSV60980115; called by mutect2, varscan2
- TNFAIP3 | c.1428G>A p.M476I | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV52800875; called by muse, mutect2, varscan2
- TRBV23-1 | c.220C>G p.L74V | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.82); PolyPhen benign (0.055); catalogued as rs1281405531; called by muse, mutect2, varscan2
- VPS54 | c.2775G>C p.L925F | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as COSV55444653; called by muse, mutect2, varscan2
- WNK1 | c.6742G>A p.D2248N (on ENST00000315939 / NM_018979.4; = p.D2000N on NM_014823.3) | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57274782; called by muse, mutect2, varscan2
- ZBED2 | c.110C>G p.P37R | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs964126153; called by muse, mutect2, varscan2
- ZFP36 | c.593C>T p.S198F (on ENST00000594442; = p.S192F on NM_003407.5) | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV99954005; called by muse, mutect2, varscan2
- ZNF230 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.818); catalogued as rs765138286; called by muse, mutect2, varscan2
- ZNF436 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.77); PolyPhen benign (0.058); catalogued as COSV58358531; called by muse, mutect2, varscan2
- ZNF799 | c.776C>T p.S259F | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV101345305; called by muse, mutect2, varscan2
- ZSCAN22 | c.541G>C p.E181Q | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV61639424; called by muse, mutect2, varscan2
- ZSCAN23 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV57043277; called by muse, mutect2, varscan2
- ABCB1 | c.3126C>G p.F1042L | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- ADGRG2 | c.327C>G p.I109M (on ENST00000379869 / NM_001079858.3; = p.I106M on NM_005756.4) | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- AKAP9 | c.10258G>C p.E3420Q (on ENST00000359028; = p.E3396Q on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- ALDH1L1 | c.2647G>C p.D883H | Missense Mutation (SNP) | VAF 13/159 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ALPK1 | c.1556C>G p.S519C | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- ANK2 | c.7936G>C p.E2646Q | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- ATP11A | c.1855G>C p.E619Q | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.062); called by muse, mutect2
- BRPF1 | c.418G>C p.E140Q | Missense Mutation (SNP) | VAF 38/219 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- C21orf58 | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- CACNA1H | c.6805G>C p.E2269Q | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.149); called by mutect2, varscan2
- CATSPERG | c.933G>T p.Q311H | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CD19 | c.546G>C p.Q182H | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CD1C | c.80C>A p.S27Y | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.467); called by mutect2, varscan2
- CD79B | c.189G>A p.M63I | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.86); PolyPhen benign (0); called by mutect2, varscan2
- CDC73 | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.764); called by muse, varscan2
- CEP126 | c.2218G>A p.D740N | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFAP57 | c.3595G>C p.E1199Q (on ENST00000372492 / NM_001378189.1; = p.E1232Q on NM_001195831.3) | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- CHST13 | c.724C>A p.P242T | Missense Mutation (SNP) | VAF 36/246 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CLIC5 | c.176del p.V59Gfs*72 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel, varscan2
- COL11A2 | c.3437G>A p.R1146K (on ENST00000341947 / NM_080680.3; = p.R1039K on NM_080679.2) | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- COQ8A | c.1346C>G p.S449C | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- CPB1 | c.884C>G p.S295C | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- CRTC2 | c.141C>G p.I47M | Missense Mutation (SNP) | VAF 30/263 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CUBN | c.8100C>G p.I2700M | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- DIP2C | c.808C>T p.R270* | Nonsense Mutation (SNP) | VAF 18/102 reads (18%) | called by muse, mutect2, varscan2
- DISP2 | c.1919C>T p.S640F | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.487); called by muse, mutect2
- DNAH5 | c.10114G>C p.D3372H | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DPF1 | c.217G>T p.G73C | Missense Mutation (SNP) | VAF 33/265 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DYNC2H1 | c.4721A>G p.Y1574C | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- EIF2B2 | c.847G>C p.D283H | Missense Mutation (SNP) | VAF 19/176 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- EMB | c.659C>G p.T220R | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- EME2 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 28/213 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- EML4 | c.1087G>C p.E363Q | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- EN1 | c.437G>C p.R146T | Missense Mutation (SNP) | VAF 34/252 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- EPN1 | c.589G>C p.E197Q | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, varscan2
- EXOC2 | c.1992+1G>T p.X664_splice | Splice Site (SNP) | VAF 5/42 reads (12%) | called by muse, mutect2, varscan2
- FAM228B | c.175G>C p.D59H | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, mutect2
- FREM3 | c.133T>C p.Y45H | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GABRG2 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.992); called by muse, varscan2
- GNAS | c.1441G>T p.E481* | Nonsense Mutation (SNP) | VAF 28/374 reads (7%) | called by muse, mutect2
- GON4L | c.3829G>C p.E1277Q | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GPATCH2L | c.149A>C p.D50A | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- H3-2 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- HACE1 | c.874C>G p.L292V | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); called by muse, mutect2
- HCN3 | c.2281G>C p.E761Q | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- HERC2 | c.12169G>A p.E4057K | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.04); called by mutect2, varscan2
- IL18R1 | c.1055G>C p.R352T | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- ITPR1 | c.8118G>A p.M2706I (on ENST00000354582; = p.M2651I on NM_002222.7) | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- JAKMIP3 | c.373G>T p.D125Y | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, varscan2
- KANK1 | c.1906G>C p.D636H | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KIF27 | c.2842G>C p.D948H | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); called by mutect2, varscan2
- KMT2B | c.4062G>C p.M1354I | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- KMT2C | c.10316C>G p.S3439C | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.395); called by muse, mutect2
- KPNA6 | c.648-1G>C p.X216_splice | Splice Site (SNP) | VAF 7/51 reads (14%) | called by muse, mutect2, varscan2
- KRT6A | c.941C>G p.S314* | Nonsense Mutation (SNP) | VAF 19/163 reads (12%) | called by muse, mutect2, varscan2
- LGR4 | c.742C>G p.P248A | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- LILRA4 | c.260C>T p.S87F | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- MAGEC1 | c.1454C>T p.S485F | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.485); called by mutect2, varscan2
- MAP4K3 | c.1204G>C p.E402Q | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.062); called by muse, mutect2
- MB21D2 | c.537C>G p.F179L | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- MDM4 | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- MED26 | c.1235A>G p.E412G | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- MROH1 | c.1830C>T p.F610= | Splice Region (SNP) | VAF 20/226 reads (9%) | called by muse, mutect2
- MYBL1 | c.808G>T p.E270* | Nonsense Mutation (SNP) | VAF 6/54 reads (11%) | called by mutect2, varscan2
- NADSYN1 | c.1993G>C p.E665Q | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.075); called by muse, mutect2
- NBPF11 | c.2269G>A p.E757K | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- NFAT5 | c.2485G>C p.D829H | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- NFKBIE | c.1459G>C p.D487H (on ENST00000275015; = p.D348H on NM_004556.3) | Missense Mutation (SNP) | VAF 15/156 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NPHS2 | c.1111G>C p.E371Q | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- NRXN3 | c.2851G>A p.D951N (on ENST00000335750 / NM_001330195.2; = p.D578N on NM_004796.6) | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NT5C3A | c.193G>C p.E65Q (on ENST00000610140 / NM_001374335.1; = p.E31Q on NM_016489.13) | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- NWD1 | c.1830G>C p.Q610H | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- OGG1 | c.1040G>C p.R347T | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.055); called by mutect2, varscan2
- OR10H4 | c.433C>T p.L145F | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- OR7D2 | c.288C>A p.D96E | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); called by mutect2, varscan2
- OSTM1 | c.946C>G p.L316V | Missense Mutation (SNP) | VAF 57/125 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- PHF14 | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); called by mutect2, varscan2
- PHF2 | c.389C>G p.P130R | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.031); called by muse, mutect2
- PLTP | c.1326C>G p.I442M | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT tolerated (0.66); PolyPhen benign (0.031); called by muse, mutect2
- POLG | c.999G>T p.Q333H | Missense Mutation (SNP) | VAF 22/255 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.188); called by muse, mutect2
- PPP1R14A | c.169G>C p.D57H | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- PPP4R3A | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 25/233 reads (11%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- RDX | c.943C>T p.Q315* | Nonsense Mutation (SNP) | VAF 20/126 reads (16%) | called by muse, mutect2, varscan2
- RIC8A | c.85-6C>T | Splice Region (SNP) | VAF 12/90 reads (13%) | called by muse, mutect2, varscan2
- ROBO2 | c.2408G>C p.G803A | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- RRAS2 | c.281C>G p.S94* | Nonsense Mutation (SNP) | VAF 17/88 reads (19%) | called by muse, mutect2, varscan2
- SCN8A | c.3131G>T p.C1044F | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- SERPINF1 | c.141C>G p.F47L | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SIPA1L2 | c.1343C>G p.S448C | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- SLC30A9 | c.379C>G p.Q127E | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SLC6A1 | c.1509C>A p.F503L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.458); called by mutect2, varscan2
- SMARCD1 | c.1066G>C p.E356Q | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SMARCD1 | c.1360G>T p.D454Y | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); called by mutect2, varscan2
- SORL1 | c.2503G>C p.E835Q | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, varscan2
- SOX10 | c.52G>C p.E18Q | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.303); called by muse, varscan2
- STIL | c.1087G>C p.E363Q | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- SYTL5 | c.1351C>G p.L451V | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TAOK1 | c.202G>C p.E68Q | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TAOK1 | c.1144G>A p.D382N | Missense Mutation (SNP) | VAF 12/161 reads (7%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.515); called by muse, mutect2
- TBC1D1 | c.2139del p.R715Gfs*38 | Frame Shift Del (DEL) | VAF 4/33 reads (12%) | called by mutect2, varscan2
- TBC1D1 | c.2143del p.R715Gfs*38 | Frame Shift Del (DEL) | VAF 5/39 reads (13%) | called by mutect2*, pindel, varscan2*
- TECPR2 | c.3707G>C p.G1236A | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.081); called by muse, mutect2
- TGM2 | c.1620G>C p.K540N | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.063); called by muse, mutect2
- TLR4 | c.602T>A p.M201K (on ENST00000355622 / NM_138554.5; = p.M161K on NM_003266.4) | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.93); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMC5 | c.2356C>G p.L786V (on ENST00000396229 / NM_001105248.1; = p.L540V on NM_024780.5) | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRPC4 | c.2051G>C p.R684T | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.179); called by muse, mutect2
- TRPS1 | c.3169G>A p.E1057K (on ENST00000220888 / NM_001330599.2; = p.E1070K on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/177 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TSC22D1 | c.1990C>G p.Q664E | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- TUBA4A | c.1033G>A p.D345N | Missense Mutation (SNP) | VAF 17/206 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.926); called by muse, mutect2
- UNG | c.753C>G p.F251L (on ENST00000242576 / NM_080911.3; = p.F242L on NM_003362.4) | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- VN1R5 | c.209C>T p.T70I | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- WDR62 | c.2676G>C p.E892D | Missense Mutation (SNP) | VAF 23/181 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WNT10A | c.270G>C p.Q90H | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.081); called by muse, mutect2
- WWC1 | c.240G>T p.Q80H | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.914); called by muse, mutect2
- ZNF572 | c.1041G>C p.Q347H | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.238); called by mutect2, varscan2
- ZNF649 | c.943G>C p.E315Q | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2
- ACLY | c.369C>T p.I123= | Silent (SNP) | VAF 6/42 reads (14%) | called by mutect2, varscan2
- AKR1E2 | c.228G>A p.K76= | Silent (SNP) | VAF 8/64 reads (13%) | called by muse, mutect2, varscan2
- ALDOA | c.201G>A p.K67= (on ENST00000642816 / NM_001243177.4; = p.K13= on NM_184041.5) | Silent (SNP) | VAF 20/159 reads (13%) | called by muse, mutect2, varscan2
- ARHGAP45 | c.2850C>G p.L950= | Silent (SNP) | VAF 33/363 reads (9%) | called by muse, mutect2
- ARVCF | c.2268G>A p.R756= | Silent (SNP) | VAF 11/135 reads (8%) | catalogued as rs1462057431; called by muse, mutect2
- ASXL2 | c.810C>T p.D270= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs774594873; called by mutect2, varscan2
- ATG2A | c.2340G>A p.K780= | Silent (SNP) | VAF 14/106 reads (13%) | called by muse, mutect2, varscan2
- ATP13A5 | c.28C>A p.R10= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as rs148053034, COSV60874618; called by muse, mutect2, varscan2
- AURKC | c.540G>A p.V180= (on ENST00000302804 / NM_001015878.2; = p.V146= on NM_003160.3) | Silent (SNP) | VAF 16/109 reads (15%) | catalogued as rs556298887, COSV57139126; called by muse, mutect2, varscan2
- CCDC102B | c.1332G>T p.L444= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV100102759; called by mutect2, varscan2
- CCDC150 | c.714C>G p.L238= | Silent (SNP) | VAF 7/64 reads (11%) | called by muse, mutect2
- CDHR2 | c.237G>A p.V79= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as COSV56144552; called by muse, mutect2, varscan2
- CENPF | c.7959G>C p.L2653= | Silent (SNP) | VAF 5/41 reads (12%) | called by muse, mutect2, varscan2
- CEP170B | c.1695C>T p.L565= (on ENST00000453495; = p.L494= on NM_015005.3) | Silent (SNP) | VAF 25/150 reads (17%) | catalogued as rs1047547734; called by muse, mutect2, varscan2
- CFAP65 | c.1713G>A p.L571= | Silent (SNP) | VAF 11/135 reads (8%) | catalogued as rs1430980736; called by muse, mutect2
- CHI3L2 | c.688C>T p.L230= | Silent (SNP) | VAF 13/85 reads (15%) | called by muse, mutect2, varscan2
- CPN2 | c.1098C>G p.L366= | Silent (SNP) | VAF 12/43 reads (28%) | called by muse, mutect2, varscan2
- CYB5R3 | c.864G>A p.L288= | Silent (SNP) | VAF 6/40 reads (15%) | called by mutect2, varscan2
- DCAF8L2 | c.511C>T p.L171= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as rs749840777; called by muse, mutect2, varscan2
- DNAH6 | c.8901G>T p.L2967= | Silent (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2, varscan2
- DOT1L | c.3514C>T p.L1172= | Silent (SNP) | VAF 18/153 reads (12%) | catalogued as rs774133943; called by mutect2, varscan2
- DSCAML1 | c.1152G>A p.L384= (on ENST00000321322; = p.L324= on NM_020693.4) | Silent (SNP) | VAF 11/46 reads (24%) | called by muse, varscan2
- EEF2K | c.774C>T p.F258= | Silent (SNP) | VAF 16/134 reads (12%) | catalogued as rs1353138460, COSV53787877; called by muse, mutect2, varscan2
- EVC | c.2064G>A p.L688= | Silent (SNP) | VAF 10/104 reads (10%) | called by muse, mutect2
- FAT4 | c.4797C>T p.L1599= | Silent (SNP) | VAF 5/24 reads (21%) | called by mutect2, varscan2
- GOLGB1 | c.5193C>G p.V1731= | Silent (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2
- IL7R | c.735C>T p.I245= | Silent (SNP) | VAF 33/177 reads (19%) | called by muse, mutect2, varscan2
- IQCG | c.135C>T p.I45= | Silent (SNP) | VAF 25/151 reads (17%) | called by muse, mutect2, varscan2
- IST1 | c.369C>G p.L123= (on ENST00000535424 / NM_001270976.1; = p.L110= on NM_014761.4) | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as rs1382977609; called by muse, mutect2
- ITGA1 | c.1525C>T p.L509= | Silent (SNP) | VAF 7/82 reads (9%) | called by mutect2, varscan2
- JAK1 | c.2349C>G p.L783= | Silent (SNP) | VAF 18/156 reads (12%) | called by muse, varscan2
- JAKMIP3 | c.516G>A p.L172= | Silent (SNP) | VAF 22/154 reads (14%) | called by muse, varscan2
- KMT2C | c.9852C>A p.V3284= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as COSV100078052; called by muse, mutect2, varscan2
- LAT2 | c.687G>A p.G229= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs782258496; called by mutect2, varscan2
- LDLRAD3 | c.372C>G p.L124= | Silent (SNP) | VAF 12/94 reads (13%) | catalogued as rs1430218120; called by muse, mutect2, varscan2
- LONP1 | c.2241G>T p.G747= | Silent (SNP) | VAF 18/152 reads (12%) | called by mutect2, varscan2
- LRIG1 | c.360C>A p.L120= | Silent (SNP) | VAF 14/80 reads (18%) | called by muse, mutect2
- MAD1L1 | c.756C>T p.L252= | Silent (SNP) | VAF 17/109 reads (16%) | catalogued as COSV99063464, COSV99767786; called by muse, mutect2, varscan2
- MAPK8IP1 | c.27G>A p.L9= | Silent (SNP) | VAF 14/67 reads (21%) | called by muse, mutect2, varscan2
- MAPKAPK2 | c.180C>T p.I60= | Silent (SNP) | VAF 38/434 reads (9%) | catalogued as rs782320757; called by muse, mutect2
- MAST3 | c.654C>T p.I218= | Silent (SNP) | VAF 52/577 reads (9%) | catalogued as rs1399297652; called by muse, mutect2
- MDN1 | c.1944C>T p.F648= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV65527973; called by mutect2, varscan2
- MEN1 | c.1668C>G p.L556= | Silent (SNP) | VAF 26/302 reads (9%) | called by muse, mutect2
- MINDY2 | c.780G>A p.Q260= | Silent (SNP) | VAF 12/159 reads (8%) | called by muse, mutect2
- MOCS3 | c.636C>T p.I212= | Silent (SNP) | VAF 18/284 reads (6%) | called by muse, mutect2
- MYO15A | c.120C>T p.F40= | Silent (SNP) | VAF 20/125 reads (16%) | called by muse, mutect2, varscan2
- MYO5B | c.1317C>A p.I439= | Silent (SNP) | VAF 23/133 reads (17%) | called by muse, mutect2, varscan2
- NEK8 | c.81G>A p.Q27= | Silent (SNP) | VAF 24/332 reads (7%) | called by muse, mutect2
- NRBP2 | c.24G>A p.P8= | Silent (SNP) | VAF 11/69 reads (16%) | called by muse, mutect2, varscan2
- NRROS | c.246C>G p.L82= | Silent (SNP) | VAF 10/72 reads (14%) | called by muse, mutect2, varscan2
- NUDT1 | c.459G>A p.K153= (on ENST00000397048 / NM_198952.1; = p.K130= on NM_002452.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 12/140 reads (9%) | catalogued as rs747740732, COSV56130931, COSV99770937; called by mutect2, varscan2
- OR2W1 | c.81G>C p.L27= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as rs926839522; called by muse, mutect2, varscan2
- PARP1 | c.795C>G p.L265= | Silent (SNP) | VAF 17/157 reads (11%) | called by muse, mutect2, varscan2
- PARS2 | c.237G>A p.L79= | Silent (SNP) | VAF 7/42 reads (17%) | called by muse, mutect2
- PCDHGA6 | c.1827C>G p.L609= | Silent (SNP) | VAF 25/179 reads (14%) | catalogued as COSV54051068; called by muse, mutect2, varscan2
- PDZD4 | c.1581C>T p.F527= | Silent (SNP) | VAF 9/72 reads (13%) | called by muse, mutect2, varscan2
- PLCL2 | c.2850C>T p.L950= (on ENST00000615277 / NM_001144382.2; = p.L824= on NM_015184.5) | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as rs771347553, COSV101196941; called by muse, varscan2
- PLCL2 | c.2868C>T p.L956= (on ENST00000615277 / NM_001144382.2; = p.L830= on NM_015184.5) | Silent (SNP) | VAF 16/108 reads (15%) | catalogued as rs1488483664, COSV101196565; called by muse, varscan2
- PLD4 | c.1278G>A p.V426= | Silent (SNP) | VAF 29/147 reads (20%) | called by muse, mutect2, varscan2
- PPP1R36 | c.858G>A p.G286= | Silent (SNP) | VAF 4/15 reads (27%) | called by mutect2, varscan2
- PROC | c.21C>T p.L7= | Silent (SNP) | VAF 16/176 reads (9%) | catalogued as COSV99300849; called by muse, mutect2
- RIF1 | c.1437C>T p.I479= | Silent (SNP) | VAF 8/76 reads (11%) | called by mutect2, varscan2
- RIN1 | c.1836C>G p.L612= | Silent (SNP) | VAF 24/208 reads (12%) | catalogued as rs1364661279; called by muse, mutect2, varscan2
- SLC25A10 | c.351G>A p.G117= | Silent (SNP) | VAF 26/152 reads (17%) | called by muse, mutect2, varscan2
- SLC5A7 | c.387C>G p.L129= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV50898352; called by mutect2, varscan2
- SNX25 | c.2064G>A p.L688= | Silent (SNP) | VAF 8/66 reads (12%) | called by muse, mutect2, varscan2
- SPEF2 | c.1056C>T p.L352= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as rs1476782605; called by muse, varscan2
- STX18 | c.426G>A p.L142= | Silent (SNP) | VAF 10/53 reads (19%) | called by muse, mutect2, varscan2
- SYN1 | c.276T>G p.A92= | Silent (SNP) | VAF 39/278 reads (14%) | called by muse, mutect2, varscan2
- TCIM | c.216A>G p.Q72= | Silent (SNP) | VAF 9/60 reads (15%) | called by muse, mutect2, varscan2
- TERB1 | c.2118G>T p.R706= | Silent (SNP) | VAF 12/108 reads (11%) | called by muse, mutect2, varscan2
- TET3 | c.5037G>A p.K1679= | Silent (SNP) | VAF 23/131 reads (18%) | called by muse, mutect2, varscan2
- TTN | c.88011C>T p.F29337= (on ENST00000591111; = p.F21913= on NM_003319.4) | Silent (SNP) | VAF 18/95 reads (19%) | catalogued as rs769177976; ClinVar: likely benign; called by muse, mutect2, varscan2
- TTYH1 | c.39G>T p.V13= | Silent (SNP) | VAF 18/122 reads (15%) | called by muse, mutect2, varscan2
- WLS | c.1047C>T p.L349= | Silent (SNP) | VAF 8/62 reads (13%) | called by muse, varscan2
- ZNF534 | c.660C>T p.I220= (on ENST00000332323 / NM_001143939.3; = p.I207= on NM_001143938.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/56 reads (13%) | called by muse, mutect2, varscan2
- AC004951.2 | n.400C>T | RNA (SNP) | VAF 21/165 reads (13%) | catalogued as rs1303511741; called by muse, mutect2, varscan2
- AC016747.4 | n.490G>C | RNA (SNP) | VAF 10/50 reads (20%) | called by muse, mutect2, varscan2
- AC107023.1 | chr12:40444122 G>T | 5'Flank (SNP) | VAF 15/50 reads (30%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73845976 G>A | 5'Flank (SNP) | VAF 6/33 reads (18%) | called by mutect2, varscan2
- ASL | c.655+22C>T | Intron (SNP) | VAF 17/133 reads (13%) | catalogued as rs774863220; called by muse, mutect2, varscan2
- BCL10 | c.-1C>A | 5'UTR (SNP) | VAF 20/231 reads (9%) | called by muse, mutect2
- BORA | c.-125G>C | 5'UTR (SNP) | VAF 9/69 reads (13%) | called by mutect2, varscan2
- CCDC136 | c.*107C>T | 3'UTR (SNP) | VAF 19/61 reads (31%) | catalogued as rs1021655878; called by muse, mutect2, varscan2
- CD19 | c.356-51C>T | Intron (SNP) | VAF 11/72 reads (15%) | catalogued as rs1184939431; called by muse, mutect2, varscan2
- CDH2 | c.173-22603G>C | Intron (SNP) | VAF 7/37 reads (19%) | called by muse, mutect2, varscan2
- CFAP43 | c.417-4419C>G | Intron (SNP) | VAF 7/49 reads (14%) | called by muse, mutect2, varscan2
- COL6A4P1 | n.355G>C | RNA (SNP) | VAF 17/71 reads (24%) | called by muse, mutect2, varscan2
- CRELD1 | c.1049-398C>G | Intron (SNP) | VAF 13/59 reads (22%) | called by muse, mutect2, varscan2
- CREM | c.698-5344C>G | Intron (SNP) | VAF 12/114 reads (11%) | catalogued as rs749982688; called by mutect2, varscan2
- CRYBG2 | c.4039-97G>C | Intron (SNP) | VAF 5/38 reads (13%) | called by mutect2, varscan2
- DNAH14 | c.6033+1105G>C | Intron (SNP) | VAF 8/59 reads (14%) | called by muse, mutect2, varscan2
- EDN3 | c.53-42C>G | Intron (SNP) | VAF 10/73 reads (14%) | called by muse, mutect2
- EML3 | c.*146G>A | 3'UTR (SNP) | VAF 28/304 reads (9%) | called by muse, mutect2
- FAS | c.*1411C>T | 3'UTR (SNP) | VAF 8/67 reads (12%) | called by muse, mutect2, varscan2
- GNG7 | c.-78+3349G>A | Intron (SNP) | VAF 19/161 reads (12%) | called by muse, mutect2, varscan2
- HERPUD1 | c.-60G>C | 5'UTR (SNP) | VAF 42/350 reads (12%) | catalogued as rs1291675196, COSV55862568; called by muse, mutect2, varscan2
- INSL3 | c.191-14C>T | Intron (SNP) | VAF 17/157 reads (11%) | called by muse, mutect2, varscan2
- KATNBL1 | c.883-604T>C | Intron (SNP) | VAF 4/34 reads (12%) | catalogued as rs1353240239; called by muse, mutect2
- KCNIP3 | c.182-27182C>G | Intron (SNP) | VAF 12/79 reads (15%) | called by muse, mutect2, varscan2
- LINC01559 | n.539G>T | RNA (SNP) | VAF 18/88 reads (20%) | called by muse, mutect2, varscan2
- LINC02381 | n.166C>G | RNA (SNP) | VAF 10/68 reads (15%) | called by muse, mutect2, varscan2
- MACF1 | c.15832-9321G>C | Intron (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2, varscan2
- MAPK9 | c.617-201C>G | Intron (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2
- MRNIP | c.537+23C>G | Intron (SNP) | VAF 8/67 reads (12%) | called by muse, mutect2, varscan2
- MXD3 | c.*36C>T | 3'UTR (SNP) | VAF 10/61 reads (16%) | catalogued as rs778656609; called by mutect2, varscan2
- NDUFA10 | chr2:240025349 G>C | 5'Flank (SNP) | VAF 14/115 reads (12%) | called by muse, mutect2, varscan2
- NDUFV1 | chr11:67604664 G>C | 5'Flank (SNP) | VAF 7/68 reads (10%) | catalogued as rs547534234; called by mutect2, varscan2
- PRDM10 | chr11:130003427 G>C | 5'Flank (SNP) | VAF 8/73 reads (11%) | catalogued as rs1035313069; called by mutect2, varscan2
- PSTPIP1 | c.37-10277A>G | Intron (SNP) | VAF 7/55 reads (13%) | catalogued as rs1433736046, COSV51200834; called by muse, varscan2
- ROBO2 | c.3761-2313G>A | Intron (SNP) | VAF 9/34 reads (26%) | called by muse, mutect2, varscan2
- SCAI | c.1399+1859_1399+1865delinsTCCAGAT | Intron (ONP) | VAF 3/31 reads (10%) | called by mutect2*, pindel
- SLC35B1 | c.481+10G>C | Intron (SNP) | VAF 8/133 reads (6%) | catalogued as rs1401439428; called by muse, mutect2
- TBC1D31 | c.-4C>T | 5'UTR (SNP) | VAF 15/115 reads (13%) | catalogued as rs1241438829; called by muse, mutect2, varscan2
- TECR | c.384-12C>G | Intron (SNP) | VAF 40/275 reads (15%) | catalogued as rs528973592; called by muse, mutect2, varscan2
- TK2 | c.31+278C>T | Intron (SNP) | VAF 11/167 reads (7%) | catalogued as rs1567544145; called by muse, mutect2
- TMPRSS13 | chr11:117902249 C>G | 3'Flank (SNP) | VAF 22/128 reads (17%) | called by muse, mutect2, varscan2
- TPH1 | c.*1313C>G | 3'UTR (SNP) | VAF 26/84 reads (31%) | catalogued as COSV100001141; called by muse, mutect2, varscan2
- TSEN15 | c.354-1482G>C | Intron (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2, varscan2
- UQCRB | c.*1956C>G | 3'UTR (SNP) | VAF 4/12 reads (33%) | called by mutect2, varscan2
- VAPB | c.*4499C>T | 3'UTR (SNP) | VAF 7/45 reads (16%) | catalogued as COSV55669048; called by muse, mutect2, varscan2
- WDR62 | c.2972-11C>G | Intron (SNP) | VAF 6/56 reads (11%) | catalogued as rs1157246321; called by muse, mutect2, varscan2
- YEATS2 | c.4160+11C>T | Intron (SNP) | VAF 6/33 reads (18%) | catalogued as rs367993532; called by mutect2, varscan2
- ZNF326 | c.-75C>G | 5'UTR (SNP) | VAF 16/175 reads (9%) | called by muse, mutect2
